Surgical pathology report (de-identified scan), TCGA case TCGA-08-0245, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0245-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left occipital region, biopsy: WHO glioblastoma multiforme, grade IV; see comment.
- B. Brain, "deep tumor," biopsy: WHO glioblastoma multiforme, grade IV; see comment.
- C. Brain, "brain tumor," biopsy: WHO glioblastoma multiforme, grade IV; see comment.
- D. Brain, "tumor margin," biopsy: Cerebral cortex with subpial and leptomeningeal involvement by glioblastoma multiforme; see comment.

COMMENT: This glioblastoma multiforme is highly cellular, has marked nuclear pleomorphism, abundant mitoses, multiple foci of necrosis, and well-developed microvascular proliferation. An immunoperoxidase stain for glial fibrillary acidic protein is strongly positive in many neoplastic astrocytes. On the specimen designated as "tumor margin" (slide D1), level sections demonstrate foci of neoplastic astrocytes present in a small sub-pial region accompanied by extensive leptomeningeal involvement, although the great majority of the cortex is free of neoplasm.

Intraoperative Diagnosis

FS1 (A) Brain, left occipital region, biopsy: WHO glioblastoma multiforme, grade IV. Tissue section and cytologic prep. [REDACTED]

Gross Description

The specimen is received in four parts.

Part A is received fresh from the O.R., labeled with the patient's name and medical record number only. It consists of multiple irregularly shaped fragments of pink-gray soft tissue which measure 1.1 x 0.7 x 0.3 cm

[page 2 of 2]
[REDACTED]
in aggregate. A cytologic preparation is made, and one-half of the specimen is submitted for frozen section #1 and subsequently in cassette A1. The remaining half of the specimen is submitted in cassette A2.

Part B is received in formalin, additionally labeled "deep tumor" and consists of 2 fragments of pink soft tissue which measure 1.1 x 0.6 x 0.4 cm in aggregate. It is entirely submitted in cassette B1.

Part C is received in formalin, additionally labeled "brain tumor" and consists of multiple irregularly shaped fragments of white-tan and pink soft tissue measuring 1.2 x 0.9 x 0.4 cm in aggregate. They are entirely submitted in cassette C1.

Part D is received in formalin, additionally labeled "tumor margin" and consists of a single unoriented fragment of gray-tan soft tissue which measures 2.5 x 1.2 x 0.6 cm. One surface of the specimen appears smooth, and this may represent the edge of the margin. This surface is inked blue. The specimen is then sectioned to reveal the apparent margin. It is entirely submitted in cassette C1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a [REDACTED] who now has a left occipital mass. This mass is noted in the O.R. to be necrotic.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b00d09bf-85ce-4e99-8b01-d9a3dc284c86 (TCGA-08-0245.A016E97A-0A5E-4EF7-B1C5-01496D830D48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).